Somatic mutation profile of tumor specimen TCGA-D3-A3BZ-06A (aliquot TCGA-D3-A3BZ-06A-12D-A196-08) from TCGA case TCGA-D3-A3BZ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.1 years (23,774 days).
Specimen TCGA-D3-A3BZ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfe89195-8fbf-426d-be87-63c488959e8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3BZ-10A (Blood Derived Normal), aliquot TCGA-D3-A3BZ-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24003ac3-c7ae-408a-a7e1-3d275a3205fb

The open-access MAF lists 57 somatic variants for this specimen: 50 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 6, Nonsense Mutation 3, Splice Site 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOL4 | c.1267T>G p.L423V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs267605178, COSV52337695, COSV52338459, COSV52349574; called by muse, mutect2
- ADAMTS9 | c.3497A>G p.H1166R | Missense Mutation (SNP) | VAF 38/795 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55790532; called by muse, mutect2
- ADGRL4 | c.1592A>G p.K531R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.135); catalogued as COSV66065956; called by muse, mutect2
- AKAP6 | c.5603A>C p.H1868P | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV55233436; called by muse, mutect2
- ARRDC1 | c.199T>A p.F67I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV65060240; called by muse, mutect2, varscan2
- ASAH2 | c.1471C>A p.P491T | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1475400057; called by muse, mutect2
- BTNL8 | c.1278G>C p.Q426H | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.916); catalogued as rs1172663456, COSV51461942; called by muse, mutect2, varscan2
- CCNB3 | c.4159G>C p.D1387H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV52079616; called by muse, mutect2, varscan2
- CCR8 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248468780, COSV58337990; called by muse, mutect2, varscan2
- CNTNAP3 | c.1856T>A p.L619H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV52675582; called by muse, mutect2
- CUL9 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.886); catalogued as rs559467472, COSV52734689; called by muse, mutect2
- DCST2 | c.739+1G>A p.X247_splice | Splice Site (SNP) | VAF 21/82 reads (26%) | catalogued as rs201711453; called by muse, varscan2
- ETF1 | c.913G>A p.V305I | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1286502948, COSV62127197; called by muse, mutect2
- GRIP1 | c.2416G>C p.V806L (on ENST00000359742 / NM_001379345.1; = p.V754L on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.071); catalogued as COSV54042826; called by muse, mutect2
- HBD | c.173A>C p.N58T | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53083619; called by muse, mutect2, varscan2
- HLA-DRA | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV66623111; called by muse, mutect2
- HNRNPF | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV61562249; called by muse, mutect2
- INHBC | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59006199; called by muse, mutect2, varscan2
- IQCN | c.1037T>C p.V346A | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV66577779; called by muse, mutect2
- LRRN4 | c.1307C>G p.S436C | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV101125526, COSV66646480; called by muse, mutect2
- MASTL | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV60912586; called by muse, mutect2
- MYH15 | c.3126A>C p.Q1042H | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV56319615; called by muse, mutect2
- NIPBL | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1235066215, COSV56966020; called by muse, mutect2
- NUP205 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466202537, COSV53666022; called by muse, mutect2
- NUP214 | c.2689T>C p.S897P | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63913156; called by muse, mutect2
- OR2J2 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs763691609, COSV65848388; called by muse, mutect2
- OR4M1 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV60063573; called by muse, mutect2
- OR51B6 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV66513933; called by muse, mutect2
- OTOGL | c.5979A>C p.Q1993H (on ENST00000547103; = p.Q1984H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV54017820, COSV54023705; called by muse, mutect2, varscan2
- PCDH15 | c.4240C>T p.R1414* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as rs1421575182, COSV57318786; called by muse, mutect2
- PDE1C | c.2078G>C p.R693T | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV58525602, COSV58528763; called by muse, mutect2
- PEX7 | c.833T>A p.L278H | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV59251975; called by muse, mutect2
- PRICKLE2 | c.805C>T p.R269* (on ENST00000295902; = p.R213* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 19/192 reads (10%) | catalogued as rs753970642, COSV55767918; called by muse, mutect2
- RBM47 | c.804G>C p.Q268H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV55943413; called by muse, mutect2
- SERPINB7 | c.1040A>C p.K347T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); catalogued as COSV60535784; called by muse, mutect2, varscan2
- SERPINI1 | c.223T>G p.S75A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780407275, COSV55514781; called by muse, mutect2, varscan2
- SHARPIN | c.1114A>T p.S372C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59645070; called by muse, mutect2
- SLC17A6 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV54141301, COSV54143014; called by muse, mutect2, varscan2
- TAFA4 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.163); catalogued as COSV55145967; called by muse, mutect2
- TFEB | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.559); catalogued as COSV57826893; called by muse, mutect2
- TMEM74 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52464847; called by muse, mutect2
- TMEM88 | c.71G>C p.C24S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54686996; called by muse, mutect2
- TRIM22 | c.304A>C p.K102Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV66091803; called by muse, mutect2, varscan2
- UBQLN3 | c.1461G>C p.R487S | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV61165793; called by muse, mutect2, varscan2
- USP44 | c.1102C>G p.L368V | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV51567069; called by muse, mutect2
- WSB1 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.166); catalogued as COSV52216833; called by muse, mutect2
- ZFC3H1 | c.4892C>T p.S1631L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV66435832; called by muse, mutect2, varscan2
- ZNF211 | c.1514G>C p.G505A (on ENST00000347302 / NM_198855.4; = p.G518A on NM_006385.5) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV53740587, COSV53745459; called by muse, mutect2, varscan2
- PLP1 | c.437_438dup p.G147* | Frame Shift Ins (INS) | VAF 20/102 reads (20%) | called by mutect2, pindel, varscan2
- TMEM132E | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- ADCY8 | c.1746C>T p.I582= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as rs377395326, COSV53912619; called by muse, mutect2
- HNF4G | c.354A>C p.S118= (on ENST00000354370 / NM_001330561.2; = p.S165= on NM_004133.5) | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV62973628; called by muse, mutect2
- NANOS3 | c.171G>T p.L57= (on ENST00000397555; = p.L76= on NM_001098622.2) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100188574, COSV59249956; called by muse, mutect2, varscan2
- OLFM3 | c.1161T>C p.T387= (on ENST00000338858 / NM_001288821.1; = p.T367= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV58800680; called by muse, mutect2, varscan2
- SSX2IP | c.189A>G p.E63= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1352330993, COSV60554618; called by muse, mutect2, varscan2
- WDR43 | c.1329A>T p.G443= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV56099925; called by muse, mutect2
- OBSCN | c.11660-1003C>G | Intron (SNP) | VAF 15/133 reads (11%) | catalogued as COSV99484518; called by muse, mutect2, varscan2
